Somatic mutation profile of tumor specimen TCGA-EY-A1G8-01A (aliquot TCGA-EY-A1G8-01A-11D-A13L-09) from TCGA case TCGA-EY-A1G8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 83.6 years (30,517 days).
Specimen TCGA-EY-A1G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58879b26-96c9-4c98-9f92-b15f33b60bde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1G8-10A (Blood Derived Normal), aliquot TCGA-EY-A1G8-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64fa186b-05ef-44db-a663-c93b9b6b2e97

The open-access MAF lists 2,853 somatic variants for this specimen: 2,273 protein-altering or splice-affecting, 513 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,885, Silent 513, Nonsense Mutation 325, Splice Site 33, Intron 23, RNA 21, 3'UTR 13, Splice Region 12, Frame Shift Ins 7, 5'Flank 6, Nonstop Mutation 5, Frame Shift Del 5.

Variants (750 of 2,853; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs137852516, CM021282, COSV52920162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3602C>A p.S1201* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs730881247, CD106445, CM010755, COSV57324987, COSV57362864; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AR | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555990485, CM003407, CM107345, CM1312667, COSV65956439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6392G>A p.R2131Q | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs122445101, CM960139, COSV100970861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASK | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1114167352, COSV59364220; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- CTNNB1 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV62707942; called by muse, mutect2, varscan2
- DCC | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs1085307773, COSV59101172; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- F8 | c.4379dup p.N1460Kfs*2 | Frame Shift Ins (INS) | VAF 17/41 reads (41%) | catalogued as rs387906455; ClinVar: pathogenic; called by mutect2, varscan2
- FKBP10 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs372896892, CM119703; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.3613C>T p.R1205* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs35333334, CM053912, COSV100172045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.4051C>T p.R1351* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as rs1318649487, CM138471, COSV65038966; ClinVar: pathogenic; called by muse, mutect2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918168, CM000190, COSV62348141; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAH | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs281865454, CM135793, CM1514923, COSV100188125; ClinVar: pathogenic; called by muse, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs1350620976, CM041053, COSV100583318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- RHOA | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 37/73 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV101371134, COSV69042787; called by muse, mutect2, varscan2
- SCN1A | c.4547C>T p.S1516L (on ENST00000303395 / NM_001202435.3; = p.S1505L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs139300715, CM024310, CM1511239, COSV57665028; ClinVar: uncertain significance / likely benign / likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893816, CM052921, CM113122, COSV55442605, COSV55447151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMTC3 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as rs768546704, COSV99898398; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.706T>G p.Y236D | Missense Mutation (SNP) | VAF 32/66 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782289, CM1411658, COSV52672888, COSV52675514, COSV52783032; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3989A>G p.Y1330C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100588719; called by muse, mutect2, varscan2
- A2ML1 | c.1061A>C p.N354T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100229019; called by muse, mutect2, varscan2
- AACS | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV99908052; called by muse, mutect2, varscan2
- AARS2 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55117757; called by muse, mutect2, varscan2
- AASS | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100741642, COSV100741808; called by muse, mutect2
- ABCA12 | c.5046G>T p.K1682N (on ENST00000272895 / NM_173076.3; = p.K1364N on NM_015657.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99790248; called by muse, mutect2, varscan2
- ABCA12 | c.4393G>T p.D1465Y (on ENST00000272895 / NM_173076.3; = p.D1147Y on NM_015657.3) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1559129128, COSV99790252; called by mutect2, varscan2
- ABCA12 | c.1423G>A p.E475K (on ENST00000272895 / NM_173076.3; = p.E157K on NM_015657.3) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs374329275; called by muse, mutect2, varscan2
- ABCA12 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs1283642196, COSV55954325, COSV99788064, COSV99791861; called by muse, mutect2, varscan2
- ABCA13 | c.4446G>T p.K1482N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV101330065; called by muse, mutect2, varscan2
- ABCA13 | c.6644A>C p.N2215T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV101330066; called by muse, mutect2, varscan2
- ABCA13 | c.14183G>A p.R4728Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs766502956, COSV68943781; called by muse, mutect2, varscan2
- ABCA3 | c.3597G>T p.M1199I | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100068621; called by muse, mutect2, varscan2
- ABCA5 | c.3584G>A p.R1195Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs370220843; called by muse, mutect2, varscan2
- ABCB1 | c.2212-1G>T p.X738_splice | Splice Site (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99713194; called by muse, mutect2, varscan2
- ABCB7 | c.1250T>A p.L417H (on ENST00000373394 / NM_001271696.3; = p.L418H on NM_004299.6) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99504423; called by muse, mutect2, varscan2
- ABCC11 | c.2266A>C p.S756R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV100750817; called by muse, mutect2, varscan2
- ABCC2 | c.2587C>A p.L863I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100966554; called by muse, mutect2, varscan2
- ABCD2 | c.2169T>G p.I723M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV100429536; called by muse, mutect2, varscan2
- ABCG2 | c.1618C>A p.L540I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as COSV99419386; called by muse, mutect2, varscan2
- ABCG2 | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV99419394; called by muse, mutect2, varscan2
- ABCG4 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs771746468, COSV100266802; called by muse, mutect2, varscan2
- AC013477.1 | c.2624C>A p.S875Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53653743; called by muse, mutect2, varscan2
- AC013489.1 | c.511T>G p.F171V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV99183868; called by muse, mutect2, varscan2
- AC244197.3 | c.680T>A p.L227H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100558032; called by muse, mutect2, varscan2
- ACADM | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.611); catalogued as COSV63720044, COSV63720242; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2, varscan2
- ACE | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); catalogued as COSV99327145; called by muse, mutect2, varscan2
- ACER2 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100575819; called by muse, mutect2, varscan2
- ACKR4 | c.218G>T p.R73I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99392122; called by muse, mutect2, varscan2
- ACMSD | c.933T>G p.F311L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV99299117; called by muse, mutect2, varscan2
- ACP4 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV99567712; called by muse, mutect2, varscan2
- ACSBG2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); catalogued as rs758992299, COSV53124024; called by muse, mutect2, varscan2
- ACSL4 | c.811G>T p.D271Y (on ENST00000340800 / NM_022977.2; = p.D230Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538628; called by muse, mutect2, varscan2
- ACSM2B | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV61657257; called by muse, mutect2, varscan2
- ACSM4 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV101257167; called by muse, mutect2, varscan2
- ACTRT1 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV100947607; called by muse, varscan2
- ADAM19 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57438574, COSV57441392; called by muse, mutect2, varscan2
- ADAM20 | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.109); catalogued as COSV56455771; called by muse, mutect2, varscan2
- ADAM22 | c.1942C>A p.L648I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV99717136; called by muse, mutect2, varscan2
- ADAM29 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100822036, COSV63663831; called by muse, mutect2
- ADAM29 | c.1889G>T p.C630F | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100822037; called by muse, mutect2
- ADAMTS1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373807387; called by muse, mutect2, varscan2
- ADAMTS10 | c.1783T>G p.S595A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV54359864, COSV99547004; called by muse, varscan2
- ADAMTS16 | c.1063A>C p.S355R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV57007439, COSV99941473; called by muse, mutect2, varscan2
- ADCK2 | c.544A>C p.T182P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766131767, COSV99301661; called by muse, mutect2, varscan2
- ADCY7 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471343779, COSV99576078; called by muse, mutect2, varscan2
- ADCYAP1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52485931; called by muse, mutect2, varscan2
- ADGRA1 | c.1153A>G p.T385A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV100811028; called by muse, mutect2, varscan2
- ADGRE1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151096072, COSV51672989, COSV51674141; called by muse, mutect2, varscan2
- ADGRF4 | c.1906A>C p.I636L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as COSV51958011, COSV99348464; called by muse, mutect2, varscan2
- ADGRF5 | c.4028C>T p.S1343L | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780829581, COSV99345538; called by muse, mutect2, varscan2
- ADGRG2 | c.1581G>T p.E527D (on ENST00000379869 / NM_001079858.3; = p.E524D on NM_005756.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100492331; called by muse, mutect2, varscan2
- ADGRG4 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99795693; called by muse, mutect2, varscan2
- ADGRG4 | c.1136T>G p.F379C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV99795695; called by muse, mutect2, varscan2
- ADGRG4 | c.5090C>A p.S1697* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99795582, COSV99795696; called by muse, mutect2, varscan2
- ADGRG4 | c.8946T>G p.I2982M | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99795699; called by muse, mutect2, varscan2
- ADGRG6 | c.3512C>T p.T1171I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV99747450; called by muse, mutect2, varscan2
- ADGRL2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 31/68 reads (46%) | catalogued as rs775512975, COSV54658637; called by muse, mutect2, varscan2
- ADGRL2 | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV54681169, COSV99589456; called by muse, varscan2
- ADGRL3 | c.1039G>A p.E347K (on ENST00000506720 / NM_001322402.2; = p.E279K on NM_015236.6) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101546943; called by muse, mutect2, varscan2
- ADGRL4 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs764619199, COSV66059595; called by muse, mutect2, varscan2
- ADH1B | c.496C>G p.P166A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100520786; called by muse, mutect2
- ADHFE1 | c.1007T>C p.I336T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99397899; called by muse, mutect2, varscan2
- ADNP2 | c.2237C>T p.T746M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs201552084, COSV100081246, COSV51540546; called by muse, mutect2, varscan2
- AFDN | c.1846T>G p.L616V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100653077; called by muse, mutect2, varscan2
- AFF1 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763544847, COSV100320692; called by muse, mutect2, varscan2
- AFF2 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60663924; called by muse, mutect2, varscan2
- AFF2 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV60653583; called by muse, mutect2, varscan2
- AFF2 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782036518, COSV99664377; called by muse, mutect2, varscan2
- AFF4 | c.1031A>C p.K344T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99535010; called by muse, mutect2, varscan2
- AGK | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV100814648; called by muse, mutect2, varscan2
- AHNAK | c.10044G>T p.K3348N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99946287, COSV99947809; called by muse, mutect2, varscan2
- AHNAK2 | c.11674C>T p.P3892S | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1566900940; called by muse, mutect2
- AHNAK2 | c.10887G>T p.K3629N | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV60915103, COSV60932290; called by muse, mutect2, varscan2
- AHNAK2 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs769670864, COSV100317743; called by muse, mutect2, varscan2
- AHR | c.1679A>C p.K560T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs1183193424, COSV99619766; called by muse, mutect2, varscan2
- AIDA | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as rs1228683651, COSV100388317; called by muse, mutect2, varscan2
- AJAP1 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV100981806; called by muse, mutect2, varscan2
- AK2 | c.208G>A p.D70N (on ENST00000354858; = p.D112N on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs765991265, COSV61468931; called by muse, mutect2, varscan2
- AK3 | c.152-1G>T p.X51_splice | Splice Site (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100729482; called by muse, mutect2, varscan2
- AKAP1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs749411736, COSV100027990; called by muse, mutect2
- AKNAD1 | c.2091G>T p.Q697H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV100645591, COSV62195368; called by muse, mutect2, varscan2
- AL136295.1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55303127, COSV99841751; called by muse, mutect2, varscan2
- AL441992.2 | c.444T>G p.S148R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV100223660; called by muse, mutect2, varscan2
- ALDH1A3 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100320448; called by muse, mutect2, varscan2
- ALDH3A1 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99855901; called by muse, mutect2, varscan2
- ALDH3B1 | c.948C>T p.I316= | Splice Region (SNP) | VAF 28/93 reads (30%) | catalogued as rs532748788, COSV99141931; called by muse, mutect2, varscan2
- ALG10 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.55); catalogued as COSV99848169; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG8 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100220123; called by muse, mutect2, varscan2
- ALKBH3 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100236351; called by muse, mutect2, varscan2
- ALPK2 | c.4210G>A p.D1404N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100864447; called by muse, mutect2, varscan2
- AMACR | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59462902; called by muse, mutect2, varscan2
- AMER2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs769578072, COSV63436480; called by muse, mutect2, varscan2
- AMHR2 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs375435717; called by muse, mutect2, varscan2
- AMHR2 | c.1722A>C p.*574Yext*19 | Nonstop Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99143248; called by muse, mutect2, varscan2
- AMZ2 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV100703169; called by muse, mutect2, varscan2
- ANAPC1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100594793; called by muse, mutect2, varscan2
- ANGPTL3 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.556); catalogued as COSV51995482; called by muse, mutect2, varscan2
- ANK1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as CM111493, COSV55887003; called by muse, mutect2, varscan2
- ANKRA2 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.944); catalogued as COSV99707040; called by muse, mutect2, varscan2
- ANKRD17 | c.7505G>A p.R2502Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as rs150262000; called by muse, mutect2, varscan2
- ANKRD17 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as rs145777158; called by muse, mutect2, varscan2
- ANKRD17 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100429314; called by muse, mutect2, varscan2
- ANKRD26 | c.4938G>T p.E1646D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101063252, COSV65774544; called by muse, mutect2, varscan2
- ANKRD26 | c.4116G>T p.K1372N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV101063253; called by muse, mutect2, varscan2
- ANKRD26 | c.2639C>T p.T880I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV101063254; called by muse, mutect2, varscan2
- ANKRD30A | c.1799-1G>T p.X600_splice (on ENST00000611781; = p.X544_splice on NM_052997.2) | Splice Site (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100653642; called by muse, mutect2, varscan2
- ANKRD30A | c.3635T>G p.I1212S (on ENST00000611781; = p.I1156S on NM_052997.2) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100653649, COSV64622141; called by muse, mutect2, varscan2
- ANKRD45 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1319080288, COSV100322523; called by muse, mutect2, varscan2
- ANKRD7 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.402); catalogued as COSV54554039, COSV99501169; called by muse, mutect2, varscan2
- ANO2 | c.1476G>T p.E492D (on ENST00000356134 / NM_001278597.3; = p.E496D on NM_001278596.3) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs748400409, COSV100501171; called by muse, mutect2, varscan2
- ANXA5 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV56638651, COSV99634425; called by muse, mutect2, varscan2
- AOAH | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs960341212, COSV51752746; called by muse, mutect2
- AOC1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs150589026, COSV62867995; called by muse, mutect2, varscan2
- AP1S2 | c.180-1G>T p.X60_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100236748; called by muse, mutect2
- AP3M2 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV99441710; called by muse, varscan2
- API5 | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101124544; called by muse, mutect2, varscan2
- APOA4 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs142295954, COSV63360637; called by muse, mutect2, varscan2
- APOB | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs187506285, COSV51932609, COSV51953932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3B | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as COSV100213786; called by muse, mutect2, varscan2
- APOBEC3F | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs1044974859, COSV100415210; called by muse, mutect2, varscan2
- APOBEC3G | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as rs754373002, COSV101349080; called by muse, mutect2, varscan2
- APOF | c.517A>C p.N173H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV100028933; called by muse, mutect2, varscan2
- APOL1 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100046118, COSV100046314; called by muse, mutect2, varscan2
- APOL2 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as COSV99969151; called by muse, mutect2, varscan2
- APPBP2 | c.1334T>G p.F445C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99319715; called by muse, mutect2, varscan2
- AQP6 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs751812963, COSV100210175; called by muse, mutect2, varscan2
- AQR | c.4207G>T p.E1403* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as COSV99334026; called by muse, mutect2, varscan2
- AREG | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV99144393; called by muse, mutect2, varscan2
- AREL1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs765033153, COSV62665629; called by muse, mutect2, varscan2
- ARF3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99873153; called by muse, mutect2, varscan2
- ARFGEF2 | c.5105C>A p.S1702Y | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100904289; called by muse, mutect2, varscan2
- ARHGAP18 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100936240; called by muse, mutect2, varscan2
- ARHGAP24 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV101232679, COSV101232749; called by muse, mutect2, varscan2
- ARHGAP25 | c.367C>T p.R123C (on ENST00000409202 / NM_001007231.3; = p.R116C on NM_014882.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201820537, COSV99771177; called by muse, mutect2, varscan2
- ARHGAP25 | c.1410C>A p.F470L (on ENST00000409202 / NM_001007231.3; = p.F462L on NM_014882.3) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as COSV54909752; called by muse, mutect2, varscan2
- ARHGAP26 | c.305T>A p.I102K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0.281); catalogued as COSV99191028; called by muse, mutect2, varscan2
- ARHGAP36 | c.1177T>C p.F393L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99357775; called by muse, mutect2, varscan2
- ARHGAP5 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100565445; called by muse, mutect2, varscan2
- ARHGAP6 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100272964; called by muse, mutect2, varscan2
- ARHGEF19 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV54619032; called by muse, mutect2, varscan2
- ARHGEF6 | c.2191-1G>T p.X731_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99166494; called by muse, mutect2, varscan2
- ARL13A | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100879020; called by muse, mutect2, varscan2
- ARMC10 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV100085757; called by muse, mutect2, varscan2
- ARMC2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV52900365; called by muse, mutect2, varscan2
- ARMC5 | c.2185G>T p.D729Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV99192563; called by muse, mutect2, varscan2
- ARPC5 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99664823; called by muse, mutect2, varscan2
- ARPP19 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51119184; called by muse, varscan2
- ARRB1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.958); catalogued as rs768596301, COSV63577600; called by muse, mutect2, varscan2
- ARRDC3 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99475229, COSV99475257; called by muse, mutect2
- ARRDC4 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs759457620, COSV51420299; called by muse, mutect2, varscan2
- ASB17 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.197); catalogued as COSV99407960; called by muse, mutect2, varscan2
- ASB18 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201441236; called by muse, mutect2, varscan2
- ASH1L | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100853451; called by muse, mutect2, varscan2
- ASH1L | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64208381; called by muse, mutect2, varscan2
- ASH1L | c.2879G>T p.S960I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as COSV100853452; called by muse, mutect2, varscan2
- ASIC5 | c.1333C>A p.L445I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV101611144, COSV73332922; called by muse, mutect2, varscan2
- ASPM | c.6925C>T p.L2309F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV54125318; called by muse, mutect2, varscan2
- ASPM | c.5120T>G p.F1707C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.106); catalogued as COSV99660485; called by muse, mutect2, varscan2
- ASXL1 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100039534; called by muse, mutect2, varscan2
- ASXL2 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55469906; called by muse, mutect2, varscan2
- ATAD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54879779; called by muse, mutect2, varscan2
- ATAD3B | c.*126A>G | Splice Region (SNP) | VAF 29/54 reads (54%) | catalogued as COSV100426501; called by muse, mutect2, varscan2
- ATAD5 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758365623, COSV100430002; called by muse, mutect2, varscan2
- ATM | c.4070C>A p.S1357Y | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs730881390, COSV99589882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.2867C>A p.S956Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100791303, COSV63526493; called by muse, mutect2, varscan2
- ATP10A | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs747360622, COSV63512971, COSV63522119; called by muse, mutect2, varscan2
- ATP10B | c.3593C>A p.S1198Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100515133, COSV59145634; called by muse, mutect2, varscan2
- ATP11C | c.3194C>A p.S1065Y | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100558035; called by muse, mutect2, varscan2
- ATP11C | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV100558036; called by muse, mutect2, varscan2
- ATP13A2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs756516383, COSV100454186; called by muse, varscan2
- ATP13A4 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.943); catalogued as COSV99794615; called by muse, mutect2, varscan2
- ATP2A3 | c.2135A>G p.K712R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV99989263; called by muse, mutect2, varscan2
- ATP2C1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.388); catalogued as rs775044921, COSV100146760; called by muse, varscan2
- ATP4A | c.1366-1G>T p.X456_splice | Splice Site (SNP) | VAF 42/80 reads (53%) | catalogued as COSV99382643; called by muse, mutect2, varscan2
- ATP6V1B2 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 39/104 reads (38%) | catalogued as rs777139485, COSV52352683; called by muse, mutect2, varscan2
- ATP6V1C2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs200699798, COSV99695822; called by muse, mutect2, varscan2
- ATP8A1 | c.722+2T>C p.X241_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100046371; called by muse, mutect2, varscan2
- ATRN | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV99497277; called by muse, mutect2, varscan2
- ATRNL1 | c.1681G>T p.D561Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100745802, COSV61819658; called by muse, mutect2, varscan2
- ATRNL1 | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100745804; called by muse, mutect2, varscan2
- ATXN3L | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV101019406; called by muse, mutect2, varscan2
- AWAT1 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100997207; called by muse, mutect2, varscan2
- AXDND1 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100858276; called by muse, mutect2, varscan2
- AXIN2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100196564; called by muse, mutect2
- AZGP1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99447958; called by muse, mutect2, varscan2
- AZIN1 | c.1223C>A p.S408* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100457587; called by muse, mutect2, varscan2
- B3GNT9 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as COSV54626219; called by muse, mutect2, varscan2
- B4GALT3 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100157767; called by muse, mutect2, varscan2
- BACH2 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283633800, COSV99998768, COSV99999774; called by muse, mutect2, varscan2
- BAHCC1 | c.3838G>A p.D1280N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs868971448, COSV100311712; called by muse, mutect2, varscan2
- BAIAP2L1 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.902); catalogued as rs1390139204, COSV99134246; called by muse, mutect2, varscan2
- BAIAP3 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.898); catalogued as rs756747374, COSV50105061; called by muse, mutect2, varscan2
- BCAS1 | c.725A>G p.D242G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781385361, COSV101006234; called by muse, varscan2
- BCAS3 | c.1732G>T p.E578* (on ENST00000390652 / NM_001353144.2; = p.E563* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV66775862; called by muse, mutect2, varscan2
- BCHE | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100012056; called by muse, mutect2
- BCOR | c.3015G>T p.E1005D | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100653403; called by muse, mutect2, varscan2
- BDP1 | c.4868C>A p.S1623Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1401065420, COSV100703173; called by muse, mutect2, varscan2
- BEND2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101192059; called by muse, mutect2
- BEND5 | c.1266A>C p.*422Yext*6 | Nonstop Mutation (SNP) | VAF 39/62 reads (63%) | catalogued as COSV100884124; called by muse, mutect2, varscan2
- BICC1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65862331; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV57280657, COSV99958723; called by muse, mutect2, varscan2
- BMX | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100564486; called by muse, mutect2, varscan2
- BNIPL | c.131T>C p.F44S | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99639619; called by muse, mutect2, varscan2
- BPIFA2 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53610150, COSV99487891; called by muse, mutect2, varscan2
- BRINP2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100838120; called by muse, mutect2, varscan2
- BRINP3 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs752029342, COSV66511801; called by muse, mutect2, varscan2
- BRWD1 | c.4550G>T p.R1517I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100313524; called by muse, mutect2
- BRWD1 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776605483, COSV100313527; called by muse, mutect2, varscan2
- BRWD3 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64744422; called by muse, mutect2, varscan2
- BSN | c.9040G>A p.D3014N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99608649; called by muse, mutect2, varscan2
- BTBD11 | c.1706A>C p.K569T (on ENST00000280758 / NM_001018072.2; = p.K106T on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.596); catalogued as COSV99776021; called by muse, mutect2, varscan2
- BTBD2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs1227404968, COSV55307886, COSV99724785; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, mutect2, varscan2
- BTK | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868924845, COSV100437634; called by muse, mutect2, varscan2
- BTN3A3 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs372313829, COSV55071255; called by muse, mutect2, varscan2
- BUB1B | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99806964; called by muse, mutect2, varscan2
- C10orf71 | c.1180C>A p.L394I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV100110232; called by muse, mutect2
- C10orf71 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100110234, COSV60510507; called by muse, mutect2, varscan2
- C10orf90 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1210424689, COSV99504131; called by muse, mutect2, varscan2
- C10orf90 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 54/55 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1269378553, COSV52957491, COSV52958261; called by muse, mutect2, varscan2
- C11orf42 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.046); catalogued as COSV99792126; called by muse, mutect2, varscan2
- C12orf40 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760100213, COSV61129961; called by muse, mutect2, varscan2
- C12orf50 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53894441; called by muse, mutect2, varscan2
- C17orf75 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV99858677; called by muse, mutect2, varscan2
- C19orf44 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1196514522, COSV99685231; called by muse, mutect2, varscan2
- C1QTNF9 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100129927; called by muse, mutect2, varscan2
- C1S | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100196589; called by muse, mutect2, varscan2
- C1orf112 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99609868; called by muse, mutect2, varscan2
- C1orf116 | c.1766G>T p.R589I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100847945; called by muse, mutect2, varscan2
- C1orf127 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100983490; called by mutect2, varscan2
- C1orf87 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV100967112, COSV64597771; called by muse, mutect2, varscan2
- C21orf58 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs938219762, COSV52449209; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, mutect2, varscan2
- C2CD6 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV99633215; called by muse, mutect2, varscan2
- C2orf16 | c.4916G>A p.R1639H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs199903910, COSV62675239; called by mutect2, varscan2
- C2orf69 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1345306043, COSV100178836; called by muse, mutect2, varscan2
- C3 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV99836728; called by muse, mutect2, varscan2
- C3AR1 | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV50820746; called by muse, mutect2, varscan2
- C5orf46 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs772440075, COSV59153812; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, mutect2, varscan2
- CA5B | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs939980426, COSV100590737; called by muse, mutect2, varscan2
- CAB39L | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100759572; called by muse, mutect2, varscan2
- CACNA1A | c.3897G>T p.M1299I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100802551; called by muse, mutect2, varscan2
- CACNA1B | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV53150093; called by muse, mutect2, varscan2
- CACNA1B | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402354374, COSV99497876; called by muse, mutect2, varscan2
- CACNA1E | c.3309G>T p.E1103D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as COSV100702979, COSV62396116; called by muse, mutect2, varscan2
- CACNA1F | c.4300A>C p.N1434H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544935; called by muse, mutect2, varscan2
- CACNA1F | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59904412; called by muse, mutect2, varscan2
- CACNA2D1 | c.1786G>T p.D596Y (on ENST00000356253 / NM_001366867.1; = p.D577Y on NM_000722.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100666724, COSV100666726; called by muse, mutect2, varscan2
- CACNA2D3 | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.891); catalogued as COSV99874128; called by muse, mutect2, varscan2
- CACUL1 | c.507A>C p.K169N | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100432586; called by muse, mutect2, varscan2
- CADM1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100522807; called by muse, mutect2, varscan2
- CAMSAP1 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.162); catalogued as rs776702915, COSV100409910; called by muse, mutect2, varscan2
- CAMTA1 | c.4745G>A p.R1582Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57881130, COSV57916053; called by muse, mutect2, varscan2
- CAPN5 | c.1499G>A p.R500H (on ENST00000456580; = p.R460H on NM_004055.5) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs373394985, COSV53689020; called by muse, mutect2, varscan2
- CARD10 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV99325013; called by muse, mutect2, varscan2
- CARD6 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV99620874; called by muse, mutect2, varscan2
- CARNS1 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as rs766432094, COSV57054049; called by muse, mutect2, varscan2
- CARS2 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1393002060, COSV99959685; called by muse, mutect2, varscan2
- CASP7 | c.694T>G p.W232G | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614911; called by muse, mutect2, varscan2
- CAST | c.404C>A p.T135N (on ENST00000341926; = p.T218N on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as rs368757850; called by muse, mutect2, varscan2
- CATSPERD | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101062598; called by muse, mutect2, varscan2
- CATSPERG | c.1443C>A p.F481L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99286578; called by muse, mutect2, varscan2
- CBL | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV50635508; called by muse, mutect2, varscan2
- CC2D2A | c.2682A>T p.Q894H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052793; called by muse, mutect2
- CC2D2A | c.3324A>T p.Q1108H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052794; called by muse, varscan2
- CC2D2A | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.441); catalogued as rs773571327, COSV101052795; called by muse, varscan2
- CC2D2A | c.4357A>C p.N1453H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV101052796; called by muse, mutect2, varscan2
- CCDC122 | c.659G>T p.R220I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99865978; called by muse, mutect2
- CCDC144A | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100138565, COSV60700300; called by muse, mutect2, varscan2
- CCDC144A | c.3236C>A p.S1079Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100138567; called by mutect2, varscan2
- CCDC146 | c.1638T>A p.H546Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.422); catalogued as COSV99592672; called by muse, mutect2, varscan2
- CCDC15 | c.2727C>A p.N909K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1034101292, COSV100776982; called by muse, mutect2, varscan2
- CCDC158 | c.3051G>T p.K1017N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101187264; called by muse, mutect2, varscan2
- CCDC160 | c.282T>G p.N94K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV100892119; called by muse, mutect2, varscan2
- CCDC178 | c.1736C>A p.S579* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100285099; called by muse, mutect2, varscan2
- CCDC27 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150537276, COSV99622579; called by muse, mutect2, varscan2
- CCDC38 | c.138G>A p.T46= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as rs139084164, COSV100717751; called by muse, mutect2, varscan2
- CCDC82 | c.1449C>A p.F483L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99567361; called by muse, mutect2, varscan2
- CCDC85A | c.446A>C p.K149T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV101339475; called by muse, varscan2
- CCDC88C | c.4217T>G p.I1406S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV100484911; called by muse, mutect2, varscan2
- CCDC89 | c.920G>T p.R307M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs757816918, COSV100320863; called by muse, mutect2, varscan2
- CCDC93 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1446618163, COSV100098918; called by muse, mutect2, varscan2
- CCIN | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.095); catalogued as COSV100631842, COSV58724663; called by muse, mutect2, varscan2
- CCNB3 | c.3894G>T p.E1298D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV99329186; called by muse, mutect2
- CCNH | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs1282114823, COSV56926026; called by muse, mutect2, varscan2
- CCNT1 | c.724C>A p.L242I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV99980773; called by muse, mutect2, varscan2
- CCR6 | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100551102, COSV59474435; called by muse, mutect2, varscan2
- CCRL2 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62193245; called by muse, mutect2, varscan2
- CCT4 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV101075226; called by muse, mutect2
- CCT6A | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1461796057, COSV99303498; called by muse, mutect2, varscan2
- CCT8L2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV63462430; called by muse, mutect2, varscan2
- CD163 | c.2468C>A p.S823Y | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100775612; called by muse, mutect2, varscan2
- CD28 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.683); catalogued as rs1179953211, COSV60731466; called by muse, mutect2, varscan2
- CD300LF | c.259A>C p.K87Q | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100042786, COSV56898666; called by muse, mutect2, varscan2
- CD69 | c.16T>G p.C6G | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99946108; called by muse, mutect2, varscan2
- CDC14B | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685772; called by muse, mutect2, varscan2
- CDC42BPG | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100712090; called by muse, mutect2, varscan2
- CDC6 | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99266600; called by muse, mutect2, varscan2
- CDC7 | c.999G>T p.M333I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1179927273, COSV99319765; called by muse, mutect2, varscan2
- CDCA7 | c.905G>A p.R302Q (on ENST00000347703 / NM_145810.3; = p.R381Q on NM_031942.5) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs748528043, COSV60720069, COSV60720142; called by muse, mutect2, varscan2
- CDCA7L | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1359449685, COSV100179431; called by muse, mutect2, varscan2
- CDH11 | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99217881, COSV99218614; called by muse, mutect2, varscan2
- CDH12 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1171594653, COSV101200838, COSV66444733; called by muse, mutect2, varscan2
- CDH17 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 63/72 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374501409, COSV50325497, COSV99217041; called by muse, mutect2, varscan2
- CDH19 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100051666; called by muse, mutect2, varscan2
- CDH23 | c.5780C>A p.S1927Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as CD142130, COSV99821330; called by muse, mutect2, varscan2
- CDH7 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100542515, COSV59890864; called by muse, mutect2, varscan2
- CDH7 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as rs745446929, COSV100542520; called by muse, mutect2, varscan2
- CDH8 | c.2339G>A p.G780D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181937; called by muse, mutect2, varscan2
- CDH8 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54867750; called by muse, mutect2, varscan2
- CDHR1 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs1180099020, COSV100258931; called by muse, mutect2, varscan2
- CDHR5 | c.1351G>T p.V451F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100363532; called by muse, mutect2, varscan2
- CDK13 | c.4013A>G p.N1338S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99475622; called by muse, mutect2, varscan2
- CDKAL1 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV99215599; called by muse, mutect2, varscan2
- CDKL2 | c.658A>G p.N220D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV100276988; called by muse, mutect2, varscan2
- CDKL3 | c.1396T>G p.S466A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99527903; called by muse, mutect2, varscan2
- CDKL5 | c.2472G>T p.E824D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV101184353; called by muse, mutect2, varscan2
- CDKN3 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369887; called by mutect2, varscan2
- CDRT1 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV100599891; called by muse, mutect2, varscan2
- CDRT1 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63053683; called by muse, mutect2, varscan2
- CDRT1 | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.168); catalogued as rs1466530658, COSV99887615; called by muse, mutect2
- CDSN | c.246A>C p.R82S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99456911; called by muse, mutect2, varscan2
- CEACAM5 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); catalogued as rs782676085, COSV55755398, COSV55756724; called by muse, mutect2, varscan2
- CELSR2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.937); catalogued as COSV99602965, COSV99603988; called by muse, mutect2, varscan2
- CELSR2 | c.1700A>G p.E567G | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99603989; called by muse, mutect2
- CENPC | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99893997; called by muse, mutect2, varscan2
- CENPI | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs775674652, COSV99515471; called by muse, mutect2, varscan2
- CEP126 | c.3325A>G p.R1109G | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99681104; called by muse, mutect2, varscan2
- CEP128 | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99383321; called by muse, mutect2, varscan2
- CEP135 | c.3248G>A p.R1083Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); catalogued as rs201733608, COSV57259318; called by muse, mutect2, varscan2
- CEP152 | c.1812G>T p.K604N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV57865280; called by muse, mutect2, varscan2
- CEP162 | c.844T>G p.Y282D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100002886; called by muse, mutect2, varscan2
- CEP250 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs763406705, COSV61168241; called by muse, mutect2, varscan2
- CEP290 | c.6841G>T p.E2281* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100468049, COSV58356618; called by muse, mutect2, varscan2
- CEP290 | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100468861; called by muse, mutect2, varscan2
- CES5A | c.1167C>A p.Y389* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99307613; called by muse, mutect2, varscan2
- CETN2 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV64743498; called by muse, mutect2
- CFAP251 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV56607739; called by muse, mutect2, varscan2
- CFAP251 | c.2069A>C p.K690T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs764636078, COSV99996162; called by muse, mutect2, varscan2
- CFAP43 | c.4777C>A p.L1593I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100829292; called by muse, mutect2, varscan2
- CFAP43 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs372598864, COSV53376197; called by muse, mutect2, varscan2
- CFAP45 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV63648087; called by muse, mutect2, varscan2
- CFAP53 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101274994; called by muse, mutect2, varscan2
- CFAP54 | c.6477C>A p.I2159= | Splice Region (SNP) | VAF 31/55 reads (56%) | catalogued as COSV100733202; called by muse, mutect2, varscan2
- CFD | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as rs375772213; called by muse, varscan2
- CFHR2 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100804337, COSV66382134; called by muse, mutect2, varscan2
- CFTR | c.947T>G p.F316C | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99136690; called by muse, mutect2, varscan2
- CHAC2 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV99712085; called by muse, mutect2, varscan2
- CHAT | c.1544A>C p.K515T | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as rs933692526, COSV100340247; called by muse, mutect2, varscan2
- CHD2 | c.4696C>A p.Q1566K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as COSV101245363; called by mutect2, varscan2
- CHD5 | c.1970A>G p.K657R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99313797; called by muse, mutect2, varscan2
- CHL1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs754718767, COSV56598549; called by muse, varscan2
- CHL1 | c.1163T>G p.F388C (on ENST00000397491 / NM_001253387.1; = p.F404C on NM_006614.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99851402; called by muse, mutect2, varscan2
- CHM | c.1513T>A p.L505M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100753378; called by muse, mutect2, varscan2
- CHML | c.1479A>C p.E493D | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100087468; called by muse, mutect2, varscan2
- CHPF2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99223105; called by muse, mutect2, varscan2
- CHRDL1 | c.1233G>T p.K411N (on ENST00000372045; = p.K417N on NM_145234.4) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.112); catalogued as COSV99488239; called by muse, mutect2, varscan2
- CHRM2 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100281394, COSV57777657; called by muse, mutect2, varscan2
- CHRM5 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV101271960, COSV67248573; called by mutect2, varscan2
- CHRNA7 | c.245G>T p.W82L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100180968; called by muse, mutect2, varscan2
- CHRNB3 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51497825, COSV99251223; called by muse, mutect2
- CHST1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346085, COSV100346163; called by muse, mutect2, varscan2
- CHSY1 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752317596, CM141063, COSV54251139, COSV54254124; called by muse, mutect2
- CHSY3 | c.1817C>A p.S606Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV100519257, COSV59288434; called by muse, mutect2, varscan2
- CHUK | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV64917507, COSV64918255; called by muse, mutect2, varscan2
- CIAO1 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs191488251, COSV55530697; called by muse, mutect2, varscan2
- CILP2 | c.2896C>T p.R966C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs1295996198, COSV99364719; called by muse, mutect2, varscan2
- CKAP4 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100952467; called by muse, mutect2, varscan2
- CKAP5 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100370862; called by muse, mutect2, varscan2
- CLCN1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as rs748415883, COSV100577817; called by muse, mutect2, varscan2
- CLIP4 | c.1707G>T p.Q569H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.275); catalogued as COSV100191965; called by muse, mutect2, varscan2
- CLMP | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV101507398; called by muse, mutect2, varscan2
- CMAS | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV99982669; called by muse, varscan2
- CMYA5 | c.4595G>A p.S1532N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770202156, COSV101484108; called by muse, varscan2
- CMYA5 | c.4793T>C p.V1598A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101484110; called by muse, mutect2, varscan2
- CMYA5 | c.6752G>A p.G2251D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); catalogued as COSV101484118; called by muse, mutect2, varscan2
- CMYA5 | c.7978G>T p.E2660* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101484119; called by muse, mutect2, varscan2
- CNBD1 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs774426451, COSV73074095; called by muse, mutect2, varscan2
- CNIH2 | c.165A>C p.K55N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.143); catalogued as COSV100268459; called by muse, mutect2, varscan2
- CNNM2 | c.1547A>C p.K516T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100881729; called by muse, mutect2, varscan2
- CNOT4 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs1308899779, COSV59651637; called by muse, mutect2, varscan2
- CNOT6 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99993606; called by muse, mutect2, varscan2
- CNTD1 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as COSV100162116; called by muse, mutect2, varscan2
- CNTLN | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99264343; called by muse, mutect2, varscan2
- CNTNAP1 | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs754056108, COSV99226507; called by muse, mutect2, varscan2
- CNTNAP2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs375032955, CM139936; called by muse, mutect2, varscan2
- CNTNAP4 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100271711; called by muse, varscan2
- CNTNAP4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56676068; called by muse, varscan2
- CNTNAP5 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70479675; called by muse, mutect2, varscan2
- CNTNAP5 | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1261090777, COSV101443483; called by muse, mutect2, varscan2
- COCH | c.841G>T p.E281* (on ENST00000216361 / NM_001347720.1; = p.E216* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99363667; called by muse, mutect2, varscan2
- COL11A1 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779028602, COSV62178226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100616852; called by muse, mutect2, varscan2
- COL12A1 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs768052470, COSV100486073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL19A1 | c.2761C>G p.P921A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100506444, COSV59591883; called by muse, mutect2, varscan2
- COL1A2 | c.3861A>C p.K1287N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99799923; called by muse, mutect2, varscan2
- COL24A1 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100993456, COSV65314356; called by muse, mutect2, varscan2
- COL4A1 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101011114, COSV65428007; called by muse, mutect2, varscan2
- COL4A4 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.988); catalogued as COSV100306983; called by muse, mutect2, varscan2
- COL4A6 | c.2782T>G p.S928A | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.634); catalogued as COSV100564246; called by muse, mutect2, varscan2
- COL6A3 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs865791056, COSV55084377; called by muse, mutect2, varscan2
- COL6A6 | c.5001A>C p.E1667D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100650323; called by muse, mutect2, varscan2
- COMMD2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779093793, COSV101519909, COSV71946699; called by muse, mutect2, varscan2
- COMP | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55873986, COSV99721460; called by muse, mutect2, varscan2
- COPS4 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV100018584; called by muse, mutect2, varscan2
- COQ10B | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99827369; called by muse, mutect2, varscan2
- COQ7 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100430528; called by muse, mutect2, varscan2
- CORO2B | c.660C>A p.C220* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99963334; called by muse, mutect2, varscan2
- CORO7 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs766836793, COSV52031780, COSV99227487; called by muse, mutect2, varscan2
- CPE | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101291599; called by muse, mutect2, varscan2
- CPED1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60007924; called by muse, mutect2, varscan2
- CPLX3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs768169193, COSV100547724; called by muse, mutect2, varscan2
- CPLX4 | c.256-1G>T p.X86_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as rs1458028474, COSV100231401, COSV55313025; called by muse, mutect2
- CPNE7 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.259); catalogued as rs762215334, COSV99254752; called by mutect2, varscan2
- CPSF2 | c.1873G>T p.D625Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100102901; called by muse, mutect2
- CPSF3 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs765101532, COSV99432867; called by muse, mutect2, varscan2
- CPXCR1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99342234; called by muse, mutect2, varscan2
- CRADD | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 23/36 reads (64%) | catalogued as COSV100257637; called by muse, mutect2, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CRBN | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99214196; called by muse, mutect2, varscan2
- CRISPLD1 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100082065; called by muse, varscan2
- CRTC3 | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51595475; called by muse, mutect2, varscan2
- CRYGD | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV100006062; called by muse, mutect2
- CRYM | c.638T>G p.F213C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99561804; called by muse, mutect2, varscan2
- CSDE1 | c.1807C>T p.R603C (on ENST00000358528 / NM_001007553.3; = p.R572C on NM_007158.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV54743532; called by muse, mutect2, varscan2
- CSF2RA | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100817769; called by muse, mutect2, varscan2
- CSGALNACT1 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV100175079; called by muse, mutect2, varscan2
- CSH2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs755600756, COSV100400231; called by muse, mutect2, varscan2
- CSMD1 | c.5035G>A p.A1679T (on ENST00000520002; = p.A1678T on NM_033225.6) | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100148802; called by muse, mutect2, varscan2
- CSMD1 | c.1915C>A p.L639I (on ENST00000520002; = p.L638I on NM_033225.6) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100148806; called by muse, mutect2, varscan2
- CSMD2 | c.6023T>C p.I2008T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1457724175, COSV99591012; called by muse, mutect2
- CSMD2 | c.3608T>C p.F1203S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99591015; called by muse, mutect2, varscan2
- CSMD3 | c.7987C>T p.R2663* (on ENST00000297405 / NM_001363185.1; = p.R2559* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 44/76 reads (58%) | catalogued as rs1432657584, COSV52100177, COSV52156018; called by muse, mutect2, varscan2
- CSMD3 | c.7675G>T p.G2559C (on ENST00000297405 / NM_001363185.1; = p.G2455C on NM_052900.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52238641; called by muse, mutect2, varscan2
- CSMD3 | c.6691C>T p.R2231* (on ENST00000297405 / NM_001363185.1; = p.R2127* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs751474008, COSV52093601, COSV52154452; called by muse, mutect2, varscan2
- CSMD3 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99833549, COSV99836169; called by muse, mutect2, varscan2
- CST4 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as rs146152326, COSV54149907; called by muse, mutect2, varscan2
- CTBP2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV58333460; called by muse, mutect2, varscan2
- CTNNA3 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101049853, COSV65574596; called by mutect2, varscan2
- CTNNAL1 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100336584, COSV57703231; called by muse, mutect2, varscan2
- CTNNBL1 | c.324G>A p.E108= | Splice Region (SNP) | VAF 28/65 reads (43%) | catalogued as COSV100799558; called by muse, mutect2, varscan2
- CTPS1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs753610646, COSV65451847; called by muse, mutect2, varscan2
- CTSW | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs558628134, COSV100327390; called by muse, mutect2, varscan2
- CUL2 | c.1753C>A p.L585I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV101039171; called by muse, mutect2, varscan2
- CWC25 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs748735255; called by muse, mutect2, varscan2
- CXCL16 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs756648834, COSV52640419; called by muse, mutect2, varscan2
- CXorf58 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.705); catalogued as COSV101002944, COSV101003003; called by muse, mutect2, varscan2
- CYB5R1 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100579699, COSV61851596; called by muse, mutect2, varscan2
- CYLC1 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as rs1464395911, COSV100254740; called by muse, mutect2, varscan2
- CYP11B2 | c.852A>C p.Q284H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100011083; called by muse, mutect2, varscan2
- CYP2A13 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.347); catalogued as rs745670637, COSV57836833; called by muse, mutect2, varscan2
- CYP2C18 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 37/117 reads (32%) | catalogued as COSV99608584; called by muse, mutect2, varscan2
- CYP2C8 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs543793530, COSV64876837, COSV64877996; called by muse, mutect2, varscan2
- CYP4F3 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV55408062, COSV55413291; called by muse, mutect2, varscan2
- CYP4F8 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100358132; called by muse, mutect2, varscan2
- CYP7B1 | c.1068T>G p.I356M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100042023; called by muse, mutect2, varscan2
- CYP7B1 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV59585766, COSV59594603; called by muse, mutect2, varscan2
- CYP8B1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs536175564, COSV60225587; called by muse, mutect2, varscan2
- CYSLTR1 | c.400T>G p.L134V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.887); catalogued as COSV100964737; called by muse, mutect2, varscan2
- DAB1 | c.1437C>A p.Y479* (on ENST00000371231; = p.Y446* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV64692785; called by mutect2, varscan2
- DACH1 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV100498513, COSV100498537; called by muse, mutect2, varscan2
- DAGLA | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99944388, COSV99944436; called by muse, mutect2, varscan2
- DAOA | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV100298779, COSV61602344; called by muse, mutect2, varscan2
- DBX2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375287819, COSV60339154; called by muse, mutect2, varscan2
- DCAF10 | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.744); catalogued as COSV99647742; called by muse, mutect2, varscan2
- DCAF12L2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758641, COSV63581246; called by muse, mutect2, varscan2
- DCAF13 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.941); catalogued as rs372518680, COSV52571180; called by muse, mutect2, varscan2
- DCAF17 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761867442, COSV100266174; called by muse, mutect2, varscan2
- DCAF4 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs771941250, COSV62319294; called by muse, mutect2, varscan2
- DCC | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV59083452; called by muse, mutect2, varscan2
- DCC | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503115, COSV59112147; called by muse, mutect2, varscan2
- DCC | c.3080C>A p.S1027* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100500505, COSV59118029; called by muse, mutect2, varscan2
- DCDC1 | c.2227T>G p.L743V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as COSV100663529; called by muse, mutect2, varscan2
- DCLK2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1230886415, COSV56203727; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DDN | c.1244C>A p.S415Y | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV100305210; called by muse, mutect2, varscan2
- DDR2 | c.1760A>C p.K587T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV100906614; called by muse, mutect2, varscan2
- DDX24 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV100427973; called by muse, mutect2, varscan2
- DDX60 | c.3089G>A p.S1030N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV101190488; called by muse, mutect2, varscan2
- DEAF1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs765017164, COSV51562933; called by muse, mutect2, varscan2
- DEAF1 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV58606915; called by muse, mutect2, varscan2
- DEFB115 | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.026); catalogued as COSV68723292; called by muse, mutect2, varscan2
- DENND3 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52800541; called by muse, mutect2, varscan2
- DENND4A | c.3327C>A p.N1109K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV101475359; called by muse, mutect2, varscan2
- DENND6A | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV60768240; called by muse, mutect2, varscan2
- DGCR8 | c.1890-1G>T p.X630_splice | Splice Site (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100707984; called by muse, mutect2, varscan2
- DGKB | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99340123; called by muse, mutect2, varscan2
- DGKI | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99934968; called by muse, mutect2, varscan2
- DHX57 | c.3512C>T p.S1171L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.681); catalogued as rs1045409511, COSV99769585; called by muse, mutect2, varscan2
- DHX9 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100841218; called by muse, mutect2, varscan2
- DIAPH1 | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as COSV99526690; called by muse, mutect2, varscan2
- DIDO1 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99826035; called by muse, mutect2, varscan2
- DIP2C | c.4205G>T p.R1402I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV55150844, COSV55172534; called by muse, mutect2, varscan2
- DLAT | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99734749; called by muse, mutect2
- DLC1 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV52317037; called by muse, mutect2, varscan2
- DLEC1 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100342532; called by muse, mutect2, varscan2
- DLEU7 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs375022108, COSV68546621; called by muse, mutect2, varscan2
- DLG3 | c.1827A>C p.Q609H (on ENST00000374360 / NM_021120.4; = p.Q304H on NM_020730.3) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99529625; called by muse, mutect2, varscan2
- DLGAP1 | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100231476; called by muse, mutect2, varscan2
- DLGAP2 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs753387748, COSV101422058; called by muse, mutect2
- DLGAP2 | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101422059; called by muse, mutect2, varscan2
- DLL4 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99989847; called by muse, mutect2, varscan2
- DMD | c.6868A>C p.K2290Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as CM031166, COSV100627526; called by muse, mutect2, varscan2
- DMD | c.1234T>G p.L412V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV99922948; called by muse, mutect2, varscan2
- DMGDH | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99669080; called by muse, mutect2, varscan2
- DMRTB1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101008338; called by muse, mutect2, varscan2
- DMXL1 | c.6625C>A p.L2209I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224128; called by muse, mutect2, varscan2
- DMXL1 | c.7033C>T p.R2345W | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147021587; called by muse, mutect2, varscan2
- DNA2 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs775240304, COSV63063043; called by mutect2, varscan2
- DNAH10 | c.4231G>T p.E1411* (on ENST00000409039; = p.E1350* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV69003401; called by muse, varscan2
- DNAH5 | c.12990G>T p.K4330N | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV99450470; called by muse, mutect2, varscan2
- DNAH5 | c.2115A>C p.E705D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99450473; called by muse, mutect2
- DNAH7 | c.9658T>G p.L3220V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100415486; called by muse, mutect2, varscan2
- DNAH7 | c.8914T>G p.S2972A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100415490; called by muse, mutect2, varscan2
- DNAH8 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs772099828, COSV100545525; called by muse, mutect2, varscan2
- DNAH8 | c.10588G>T p.E3530* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV59424050; called by muse, mutect2, varscan2
- DNAH9 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV52374923; called by muse, mutect2, varscan2
- DNAI1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs565990305, COSV99646631; called by muse, mutect2, varscan2
- DNAJB14 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745989722, COSV100508499; called by muse, mutect2, varscan2
- DNAJC6 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV54781879; called by muse, mutect2, varscan2
- DNHD1 | c.12610G>T p.D4204Y | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54443062; called by muse, mutect2, varscan2
- DNTT | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs755818841, COSV64522745; called by muse, mutect2, varscan2
- DOCK10 | c.3970C>A p.L1324I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.11); catalogued as COSV51374412; called by muse, mutect2, varscan2
- DPEP3 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99262736; called by muse, mutect2, varscan2
- DPH6 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99853244; called by muse, mutect2, varscan2
- DPP8 | c.1792T>C p.S598P (on ENST00000341861 / NM_001320875.2; = p.S582P on NM_017743.6) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100202399; called by muse, mutect2, varscan2
- DRD1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs572625837, CM1414023, COSV101192469; called by muse, mutect2, varscan2
- DRD3 | c.543C>A p.C181* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99879471; called by muse, mutect2
- DRD3 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199854203, COSV55679533, COSV55681756; called by muse, mutect2, varscan2
- DRP2 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871929; called by muse, mutect2, varscan2
- DSC1 | c.2679G>T p.K893N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99937717; called by muse, mutect2, varscan2
- DSC3 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs267605145, COSV64571842; called by muse, mutect2, varscan2
- DSC3 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV64574089; called by muse, mutect2, varscan2
- DSCC1 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV58088588; called by muse, mutect2
- DSP | c.4019G>A p.R1340H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs765247380, COSV65792464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSPP | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.387); catalogued as rs199906213, COSV56807314, COSV99217455; called by muse, mutect2, varscan2
- DST | c.8305G>T p.D2769Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV99756773; called by muse, mutect2, varscan2
- DTNB | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99977426; called by muse, mutect2, varscan2
- DTX4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99915508; called by muse, mutect2, varscan2
- DUSP3 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as rs759810249, COSV56824840; called by muse, mutect2, varscan2
- DUSP5 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs1472484247, COSV100851902; called by muse, mutect2, varscan2
- DUXA | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs762740549, COSV101617136, COSV73729624; called by muse, mutect2, varscan2
- DUXA | c.231A>C p.E77D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV101617143; called by muse, varscan2
- DYNC1H1 | c.12213C>T p.I4071= | Splice Region (SNP) | VAF 48/92 reads (52%) | catalogued as rs746950373, COSV64138136; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC2H1 | c.10669G>T p.E3557* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV62085806; called by muse, mutect2, varscan2
- DYNC2I1 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV68103777; called by muse, mutect2, varscan2
- DYRK2 | c.1638G>T p.E546D (on ENST00000344096 / NM_006482.3; = p.E473D on NM_003583.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100165321; called by muse, mutect2, varscan2
- DYRK3 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100895716; called by muse, mutect2
- DYRK3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199918563, COSV100895622; called by muse, mutect2, varscan2
- DZIP1L | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100551400; called by muse, mutect2, varscan2
- DZIP1L | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs773821499, COSV100551404; called by muse, mutect2, varscan2
- DZIP3 | c.3261A>C p.K1087N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs988376535, COSV100847836; called by muse, mutect2, varscan2
- EBF1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565887, COSV100566474, COSV58177454; called by muse, mutect2, varscan2
- EBF3 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV62475179; called by muse, mutect2, varscan2
- EDA | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV65777053; called by muse, mutect2, varscan2
- EDAR | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as rs781739021, COSV99303724; called by muse, mutect2, varscan2
- EDIL3 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV56923092, COSV99676960; called by muse, mutect2, varscan2
- EFCAB6 | c.4114G>A p.D1372N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs113498685, COSV99413493; called by muse, mutect2, varscan2
- EFHC1 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100932051; called by muse, mutect2, varscan2
- EFL1 | c.3040G>T p.E1014* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99187199; called by muse, mutect2, varscan2
- EFNA4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); catalogued as rs769941477, COSV63018733; called by muse, mutect2, varscan2
- EFNB1 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.601); catalogued as COSV99214861; called by muse, mutect2, varscan2
- EGF | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as rs142198895; called by muse, mutect2, varscan2
- EGF | c.3204G>T p.K1068N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99491001; called by muse, mutect2, varscan2
- EGFL6 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100789896, COSV100789950; called by muse, mutect2, varscan2
- EHD3 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as COSV59031846; called by muse, mutect2, varscan2
- EIF2S1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1307743206, COSV99833196; called by muse, mutect2, varscan2
- EIF4G3 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV51677587; called by muse, mutect2, varscan2
- ELAC2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV100568531; called by muse, mutect2, varscan2
- ELAVL4 | c.949T>G p.F317V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836759; called by muse, mutect2, varscan2
- ELK4 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV99222395; called by muse, mutect2, varscan2
- ELMO2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs372963438, COSV51684203; called by muse, mutect2, varscan2
- ELOVL4 | c.921A>C p.K307N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100876295; called by muse, mutect2, varscan2
- EML4 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs775548568, COSV59293982; called by muse, mutect2, varscan2
- EML5 | c.5040G>T p.E1680D (on ENST00000380664; = p.E1688D on NM_183387.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV100715712; called by muse, mutect2, varscan2
- ENAM | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV101253136; called by muse, mutect2, varscan2
- ENDOU | c.392A>G p.H131R (on ENST00000422538 / NM_001172439.2; = p.H90R on NM_006025.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1565734306, COSV99968320; called by muse, mutect2, varscan2
- ENPEP | c.1521A>T p.E507D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV99487653; called by muse, mutect2, varscan2
- ENPP2 | c.2452G>T p.E818* (on ENST00000075322 / NM_001040092.3; = p.E870* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as COSV99308397; called by muse, mutect2, varscan2
- ENPP7 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV100093459; called by muse, mutect2, varscan2
- ENTPD1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100967575; called by muse, mutect2, varscan2
- ENTPD7 | c.1245C>A p.F415L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV100978424; called by muse, mutect2, varscan2
- ENTR1 | c.1249G>A p.E417K (on ENST00000357365 / NM_001039707.2; = p.E394K on NM_006643.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs369068460; called by muse, mutect2, varscan2
- EOMES | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99842009; called by muse, mutect2, varscan2
- EP400 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV100201335, COSV57778858; called by muse, mutect2, varscan2
- EPB41L3 | c.2546A>G p.E849G | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); catalogued as COSV100549371; called by muse, mutect2, varscan2
- EPB41L3 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV100549375; called by muse, mutect2, varscan2
- EPHA5 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV56630579, COSV56683300; called by muse, mutect2, varscan2
- EPHA5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs369606981, COSV56635227; called by muse, mutect2, varscan2
- EPHA7 | c.2089T>G p.L697V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100993847; called by muse, mutect2, varscan2
- EPHB2 | c.2530C>T p.R844W (on ENST00000400191 / NM_001309193.2; = p.R845W on NM_004442.7) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs55826626, COSV101007136; called by muse, mutect2, varscan2
- EPO | c.14-1G>T p.X5_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99402590; called by muse, mutect2, varscan2
- EPSTI1 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58048766; called by muse, mutect2, varscan2
- EPX | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs376090047; called by muse, mutect2, varscan2
- ERBIN | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); catalogued as rs768018667, COSV99396991; called by muse, mutect2
- ERCC6 | c.3476G>T p.R1159I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100875950; called by muse, mutect2, varscan2
- ERICH3 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58601756; called by muse, mutect2, varscan2
- ERO1B | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs970389187, COSV59242256; called by muse, mutect2, varscan2
- ERVFRD-1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.823); catalogued as rs756242354, COSV65368765; called by muse, mutect2, varscan2
- ESX1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.651); catalogued as rs1404841840, COSV101006457; called by muse, mutect2, varscan2
- ESYT1 | c.2995C>T p.R999* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as rs146217441; called by muse, mutect2, varscan2
- EWSR1 | c.1895G>T p.R632I | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.282); catalogued as COSV100130891, COSV100131554; called by muse, mutect2, varscan2
- EXOC3 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750231808, COSV100155370, COSV59268966; called by muse, mutect2, varscan2
- EXOC3 | c.1526G>T p.R509I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs1220428036, COSV100155347, COSV100155567; called by muse, mutect2, varscan2
- EXOC4 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs544415669, COSV54100755; called by muse, mutect2, varscan2
- EXPH5 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.331); catalogued as COSV99761711; called by muse, mutect2, varscan2
- EXT2 | c.1678C>T p.P560S (on ENST00000343631; = p.P593S on NM_000401.3) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100640620; called by muse, mutect2, varscan2
- EXTL3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219830248, COSV55037906; called by muse, mutect2, varscan2
- EYA1 | c.556+2T>G p.X186_splice | Splice Site (SNP) | VAF 49/124 reads (40%) | catalogued as COSV100379528; called by muse, mutect2, varscan2
- EYS | c.1741T>G p.C581G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs558477347, COSV100676584, COSV60991204; called by muse, mutect2, varscan2
- EZH2 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.434); catalogued as COSV100235765; called by muse, mutect2, varscan2
- F2RL3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1358140437, COSV50185828; called by muse, mutect2, varscan2
- F8 | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV100811579; called by muse, mutect2, varscan2
- FAAH2 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100887337; called by muse, mutect2, varscan2
- FAAH2 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV66505148; called by muse, mutect2, varscan2
- FABP7 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs372533301; called by muse, mutect2, varscan2
- FAF2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as rs1210656384, COSV99990494; called by muse, mutect2, varscan2
- FAH | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs11555097, COSV55721560; called by muse, mutect2, varscan2
- FAM114A1 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100729333; called by muse, mutect2, varscan2
- FAM160B2 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1261350983, COSV99249039; called by muse, mutect2, varscan2
- FAM161A | c.1892T>G p.F631C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101295699; called by muse, mutect2, varscan2
- FAM184A | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100137887; called by muse, mutect2, varscan2
- FAM193A | c.3299G>T p.R1100I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100219261, COSV61197170; called by muse, mutect2
- FAM81B | c.1235C>A p.S412* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV51982434; called by muse, mutect2, varscan2
- FAM83C | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100981586; called by muse, mutect2
- FAM91A1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as rs767936243, COSV58236325; called by muse, mutect2, varscan2
- FAM9B | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.417); catalogued as COSV100511007; called by muse, mutect2, varscan2
- FANCM | c.5443G>T p.G1815* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99951108; called by muse, mutect2, varscan2
- FAP | c.1992C>A p.F664L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.389); catalogued as rs1450977209, COSV99502213; called by muse, mutect2, varscan2
- FARP2 | c.2890C>A p.H964N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV50883148, COSV99884760; called by muse, mutect2, varscan2
- FASTKD1 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV70006587; called by muse, mutect2, varscan2
- FASTKD2 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs749764322, COSV99379021; called by muse, mutect2, varscan2
- FASTKD3 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99241772; called by muse, mutect2, varscan2
- FAT1 | c.9776T>G p.I3259S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as COSV101499392; called by muse, mutect2, varscan2
- FAT1 | c.5723C>A p.S1908* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV71674387; called by muse, mutect2, varscan2
- FAT2 | c.8923G>A p.E2975K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285926442, COSV99943102; called by muse, mutect2, varscan2
- FAT2 | c.7006G>T p.E2336* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs778399515, COSV55814462; called by muse, mutect2, varscan2
- FAT3 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV99966800; called by muse, mutect2, varscan2
- FAT3 | c.4636C>T p.R1546* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs866154457, COSV53094050; called by muse, mutect2, varscan2
- FAT3 | c.5228C>A p.A1743D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53112674, COSV99966803; called by muse, mutect2, varscan2
- FAT3 | c.6901C>T p.L2301F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs370503286, COSV53106024, COSV99966807; called by muse, mutect2, varscan2
- FAT3 | c.7428C>A p.F2476L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99966809; called by muse, mutect2, varscan2
- FAT3 | c.11566G>T p.E3856* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99966811, COSV99969470; called by muse, mutect2, varscan2
- FAT4 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as CD148456, COSV101272388; called by muse, mutect2, varscan2
- FBN1 | c.5935C>A p.L1979I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as COSV100355308, COSV57314883; called by muse, mutect2, varscan2
- FBN1 | c.3075C>A p.F1025L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as CD102325, COSV100355313; called by muse, mutect2
- FBXO3 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs768286240, COSV55765806; called by muse, mutect2, varscan2
- FBXO40 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779809283, COSV57528895; called by muse, mutect2, varscan2
- FBXO42 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs747404514, COSV100981821; called by muse, mutect2, varscan2
- FBXO46 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs762845625, COSV100480237; called by muse, mutect2, varscan2
- FCMR | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV65567509; called by muse, mutect2, varscan2
- FCRL4 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.083); catalogued as COSV99619923; called by muse, mutect2, varscan2
- FER | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777925363, COSV55284265; called by muse, mutect2, varscan2
- FERMT2 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as COSV100448925; called by muse, mutect2, varscan2
- FEZF2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99334776; called by muse, mutect2, varscan2
- FFAR2 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99876082; called by muse, mutect2, varscan2
- FFAR4 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV65159922, COSV65160888; called by muse, mutect2, varscan2
- FGD5 | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs771409398, COSV99548212; called by muse, mutect2, varscan2
- FGF5 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV56889985, COSV56891429; called by muse, mutect2, varscan2
- FHOD1 | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99264183; called by muse, mutect2, varscan2
- FIBIN | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100590460, COSV59412650; called by muse, mutect2, varscan2
- FIS1 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV99778957; called by muse, mutect2, varscan2
- FLG | c.9395G>T p.S3132I | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as COSV100911631; called by muse, mutect2, varscan2
- FLG2 | c.5717C>T p.S1906F | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV101165911; called by muse, mutect2, varscan2
- FLNA | c.6151C>T p.R2051W (on ENST00000369850 / NM_001110556.2; = p.R2043W on NM_001456.3) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs782560098, COSV100774753; called by muse, mutect2, varscan2
- FLNA | c.3540A>C p.Q1180H | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.637); catalogued as COSV100774754; called by muse, mutect2, varscan2
- FLNC | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs374294752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751562024, COSV54045211; called by muse, mutect2, varscan2
- FLT4 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs759344198, COSV56100969; called by muse, mutect2, varscan2
- FLVCR1 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV65323461; called by muse, mutect2, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2
- FMR1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54423800, COSV54425108; called by muse, mutect2, varscan2
- FN1 | c.3950C>A p.S1317Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100117279; called by muse, mutect2, varscan2
- FNBP4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1188186462, COSV55447440; called by muse, mutect2, varscan2
- FNIP2 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032747; called by muse, mutect2, varscan2
- FOLH1 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99923294; called by muse, mutect2, varscan2
- FOXO3 | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV100669916; called by muse, mutect2, varscan2
- FOXP2 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100646792; called by muse, mutect2, varscan2
- FOXP2 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 39/91 reads (43%) | catalogued as COSV63486238; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100436834; called by muse, mutect2, varscan2
- FRAS1 | c.11144C>A p.S3715Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53644552; called by muse, mutect2, varscan2
- FREM2 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs765737456, COSV99749059; called by muse, mutect2, varscan2
- FRG1 | c.624T>G p.N208K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99903196; called by muse, mutect2, varscan2
- FRMD3 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs569434487, COSV100418790; called by muse, mutect2, varscan2
- FRMD5 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV101296589; called by muse, mutect2, varscan2
- FRMD5 | c.530A>C p.E177A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV101296590; called by muse, mutect2, varscan2
- FRMPD3 | c.2446T>C p.S816P | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV99346407; called by muse, mutect2, varscan2
- FRMPD3 | c.4091G>C p.S1364T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99346410; called by muse, mutect2, varscan2
- FRMPD4 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101043083; called by muse, mutect2, varscan2
- FRY | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as rs1229819218, COSV66569638; called by muse, mutect2, varscan2
- FSD2 | c.219A>T p.E73D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV100575158; called by muse, mutect2, varscan2
- FSIP1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as COSV100618116; called by muse, mutect2, varscan2
- FST | c.278-1G>T p.X93_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99887221; called by muse, mutect2, varscan2
- FSTL5 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100056280, COSV100059885; called by muse, mutect2, varscan2
- FUNDC1 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs759139437, COSV100953641, COSV65181325; called by muse, mutect2, varscan2
- FUT8 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV61281838, COSV61282604; called by muse, mutect2, varscan2
- FXYD5 | c.141A>G p.P47= | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99544891; called by muse, mutect2, varscan2
- FYB2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as rs199726486, COSV100599575; called by muse, mutect2, varscan2
- G2E3 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV99249674; called by muse, mutect2, varscan2
- GABBR1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.091); catalogued as rs777523377, COSV63542264; called by muse, mutect2, varscan2
- GABRA2 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62917164; called by muse, mutect2, varscan2
- GABRA3 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100942833; called by muse, mutect2, varscan2
- GABRA6 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs780694809, COSV50895136, COSV99194568; called by mutect2, varscan2
- GABRG1 | c.806G>T p.R269I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768534395, COSV54956647, COSV54962322; called by muse, mutect2, varscan2
- GABRQ | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as rs782695736; called by muse, mutect2
- GADL1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs770223371, COSV99244474; called by muse, mutect2, varscan2
- GADL1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs138172857, COSV99244274; called by muse, mutect2, varscan2
- GALNT18 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99924776, COSV99925399; called by muse, mutect2, varscan2
- GALNT5 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771999351, COSV52037731; called by muse, mutect2, varscan2
- GALR1 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100231867; called by muse, mutect2
- GAPT | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1236181925, COSV59247394; called by muse, mutect2, varscan2
- GARNL3 | c.66T>G p.F22L | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as COSV100150346; called by muse, mutect2, varscan2
- GAS2 | c.90A>C p.E30D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV99535166; called by muse, mutect2, varscan2
- GATM | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101188295; called by muse, mutect2, varscan2
- GCAT | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs181758632, COSV99959818; called by muse, mutect2, varscan2
- GCC1 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99133784, COSV99133985; called by muse, mutect2, varscan2
- GCC2 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV100565472; called by muse, mutect2, varscan2
- GCG | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100972773, COSV64961690; called by muse, mutect2, varscan2
2,103 further variants in this file (1,523 protein-altering or splice-affecting, 513 silent, 67 other) are not listed here.
